CCDI case PBBVZZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/bf787b10-2d33-48d7-9447-5bc60630a04b

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 6.8 years (2,477 days).

Biospecimens (3 samples)
- Sample 0DIQZP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIR0B: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIR3X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
